Gene-level copy-number profile of tumor specimen ALCH-B45V-TTP1-A from ALCHEMIST case ALCH-B45V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.6 years (25,420 days).
Specimen ALCH-B45V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b90d6ed8-5f5d-4f37-aefc-2428b012f64e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B45V-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,242 have no estimate.
https://portal.gdc.cancer.gov/files/2d6bcfb5-88e4-433b-b66b-2657e5387742

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 87; copy number 2: 12,857; copy number 3: 1,944; copy number 4: 42,437; copy number 5: 892; copy number 6: 87; copy number 7: 23; copy number 10: 1; copy number 13: 4; copy number 16: 2; copy number 26: 1; copy number 38: 11.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,877,413–1,900,493, 3 genes: IRX4, IRX4-AS1, CTD-2194D22.4.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr15:25,203,227–25,247,426, 25 genes (within-gene range 0–4): SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42.
- chr17:21,284,672–21,419,870, 2 genes: MAP2K3, KCNJ12.
- chr17:50,934,989–50,948,750, 2 genes: AC005920.1, AC005920.3.
- chr19:2,977,538–2,995,179, 1 gene: TLE6.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 19 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:65,219,987–65,230,861, 2 genes, copy number 16: AL512605.1, AL512605.2.
- chr16:16,290,135–16,351,653, 11 genes, copy number 38 (within-gene range 4–38): AC136624.2, MIR3179-2, MIR3670-2, AC138969.2, MIR3180-2, PKD1P1, Y_RNA, AC138969.1, MIR6511A2, MIR6770-2, AC138969.3.
- chr18:12,984,694–12,991,173, 1 gene, copy number 10 (within-gene range 2–10): AP002449.1.
- chr22:18,715,815–18,719,341, 1 gene, copy number 26: PPP1R26P4.
- chr22:18,846,811–18,894,407, 4 genes, copy number 13: AC008132.1, BCRP7, FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 87. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
